CCDI case PBBSYU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/064a4165-2704-4de1-83d4-e737b753ec62

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.6 years (3,524 days).

Biospecimens (4 samples)
- Samples 0DG5A3, 0DG5AM (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DG5AB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG85T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
